TCGA case TCGA-G8-6324 — Lymphoid Neoplasm Diffuse Large B-cell Lymphoma (TCGA-DLBC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mature B-Cell Lymphomas; Primary site: Lymph nodes; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6a21c948-cd85-4150-8c01-83017d7dc1ed

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 43 years; Vital status: Dead; Days to death: 1,252 days (3.4 years).

Diagnoses (2)
1. Diffuse large B-cell lymphoma, NOS (the primary disease): ICD-O-3 morphology code: 9680/3; ICD-10 code: C83.3; Tissue or organ of origin: Intra-abdominal lymph nodes; Site of resection or biopsy: Intra-abdominal lymph nodes; Classification of tumor: primary; Age at diagnosis: 43.1 years (15,750 days); Year of diagnosis: 2006; AJCC staging edition: 6th; Ann Arbor clinical stage: Stage IV; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,252 days (3.4 years); Ann Arbor extranodal involvement: Yes; Sites of involvement: Lymph Node, Mesenteric / Ascites / Peritoneum, NOS.
   Pathology details: Additional pathology findings: Bone marrow discordant histology; Bone marrow malignant cells: Yes; Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CHOP-21; Days to treatment start: 25 days; Days to treatment end: 130 days; Number of cycles: 6.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Dexamethasone; Initial disease status: Progressive Disease; Regimen or line of therapy: DHAC; Days to treatment start: 390 days (1.1 years); Days to treatment end: 394 days (1.1 years); Number of cycles: 1.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Cytarabine + Dexamethasone; Initial disease status: Progressive Disease; Regimen or line of therapy: DHAC; Days to treatment start: 392 days (1.1 years); Days to treatment end: 394 days (1.1 years); Number of cycles: 1.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Days to treatment start: 501 days (1.4 years).
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 563 days (1.5 years); Days to treatment end: 591 days (1.6 years); Treatment dose: 40 Gy; Treatment outcome: Stable Disease; Number of fractions: 20; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bortezomib + Doxorubicin + Rituximab; Initial disease status: Progressive Disease; Days to treatment start: 971 days (2.7 years); Days to treatment end: 1,124 days (3.1 years); Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lenalidomide; Initial disease status: Progressive Disease; Days to treatment start: 1,148 days (3.1 years); Days to treatment end: 1,165 days (3.2 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine + Rituximab + Vinorelbine; Initial disease status: Progressive Disease; Days to treatment start: 1,172 days (3.2 years); Days to treatment end: 1,200 days (3.3 years); Number of cycles: 2.
2. Progression of diagnosis 1 (Diffuse large B-cell lymphoma, NOS), site: Lymph nodes of head, face and neck. Age at diagnosis: 44.0 years (16,088 days); Days to diagnosis: 338 days; Prior treatment: Yes.

Follow-up (4 entries)
- Day 338 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph nodes of head, face and neck; Days to progression: 338 days.
- Days to follow up: 1,252 days (3.4 years); Disease response: With Tumor.
- ECOG performance status: 1.
- Imaging type: PET; Imaging result: Negative; Timepoint: Within 2 Months After Completion of First-Course Treatment.

Molecular and laboratory tests
- BCL2 (FISH): Normal.
- BCL2 (IHC): Positive.
- BCL6 (FISH): Normal.
- BCL6 (IHC): Positive.
- CCND1 (FISH): Normal.
- CD10 (Flow Cytometry): Negative.
- CD19 (Flow Cytometry): Positive.
- CD20 (Flow Cytometry): Positive.
- CD20 (IHC): Positive.
- CD23 (Flow Cytometry): Positive.
- CD23 (IHC): Positive.
- CD5 (Flow Cytometry): Negative.
- CD5 (IHC): Negative.
- IRF4 (IHC): Positive.
- PAX5 (IHC): Positive.
- Lactate Dehydrogenase 498 IU [Blood test normal range upper: 618].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 60 kg; Height: 165.5 cm; BMI: 21.9.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-G8-6324-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.6; Intermediate dimension: 0.3; Shortest dimension: 0.2.
  Slide TCGA-G8-6324-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
- Sample TCGA-G8-6324-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-G8-6324-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: mesenteric.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Ascites/Peritoneum.
- Primary pathology: Extranodal site involvement: 1; Bone marrow sample histology: Discordant Histology.
- Tests performed: LDH level: 498; Mib 1 positive percent range: 51 - 75%; B cell genotype method: IgH PCR.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunopheotypic analysis tested: CD19.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunopheotypic analysis tested: CD10 > 30%.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunopheotypic analysis tested: BCL2; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunopheotypic analysis tested: CD20; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunopheotypic analysis tested: MUM1 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunopheotypic analysis tested: BCL6 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunopheotypic analysis tested: CD23; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 10: Immunopheotypic analysis tested: PAX5; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 11: Immunopheotypic analysis tested: CD5; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: BCL2.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 2: Genetic abnormality tested: BCL6.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 3: Genetic abnormality tested: CCND1.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.
- Drug treatment 1: Stem cell transplantation: Yes; Stem cell transplantation type: Autologous; Pharmaceutical regimen: CHOP-21 + Rituximab.
- Drug treatment 5: Stem cell transplantation: Yes; Stem cell transplantation type: Autologous; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify).
- Drug treatment 6: Pharmaceutical therapy drug name: decadron; Stem cell transplantation: Yes; Stem cell transplantation type: Autologous; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify).
- Drug treatment 9: Stem cell transplantation: Yes; Stem cell transplantation type: Autologous; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: Bortezomib, Rituximab, Doxorubicin.
- Drug treatment 12: Stem cell transplantation: Yes; Stem cell transplantation type: Autologous; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: Rituximab, Gemcitabine, Navelbine.
- Drug treatment 15: Pharmaceutical therapy drug name: Revlimid; Stem cell transplantation: Yes; Stem cell transplantation type: Autologous; Pharmaceutical regimen: Single Agent Therapy (please specify).

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,252 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,252 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 338 days.
